Somatic mutation profile of tumor specimen TCGA-DF-A2KN-01A (aliquot TCGA-DF-A2KN-01A-11D-A17W-09) from TCGA case TCGA-DF-A2KN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3.
Specimen TCGA-DF-A2KN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd0ce273-53e0-4371-9086-65635dbb9b8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2KN-10A (Blood Derived Normal), aliquot TCGA-DF-A2KN-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d831b11-374a-4ca2-b630-1b7a76027154

The open-access MAF lists 5,386 somatic variants for this specimen: 3,975 protein-altering or splice-affecting, 1,270 silent, 141 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,870, Silent 1,270, Frame Shift Del 405, Frame Shift Ins 286, Nonsense Mutation 198, Splice Site 151, Intron 55, Splice Region 47, RNA 37, 3'Flank 15, 5'Flank 14, 3'UTR 12.

Variants (750 of 5,386; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.192dup p.P65Tfs*7 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs771055189; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 12/92 reads (13%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- ARID1B | c.2162dup p.S723Ifs*27 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | catalogued as rs1554294674; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- CIC | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50590933, COSV99360194; called by muse, mutect2, varscan2
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- CPS1 | c.2391+1G>A p.X797_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as rs1553513433, COSV99242733; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 5/14 reads (36%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, varscan2
- DYSF | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as rs373585652, CM052862; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F11 | c.990dup p.T331Yfs*28 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | catalogued as rs1554082938; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.130del p.L44Wfs*111 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs193922578; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KAT6A | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1564034820, COSV55904293; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3260_3261dup p.F1088Pfs*3 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- MYBPC3 | c.2610dup p.S871Qfs*13 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | catalogued as rs397515979; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- NBN | c.1958dup p.L654Afs*5 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | catalogued as rs780235686; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1133G>T p.C378F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as CM126691, COSV55930877, COSV55952006; called by muse, mutect2, varscan2
- POMGNT1 | c.982dup p.V328Gfs*11 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs386834040; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RPGRIP1L | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs751477523, CM1212113, COSV50905127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.3291C>T p.G1097= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1234999215, COSV62115654; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel
- A4GALT | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99966635; called by muse, mutect2, varscan2
- AAAS | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV99266908; called by muse, mutect2, varscan2
- AAAS | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV99266911; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs746497630; called by mutect2, varscan2
- AARS2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV99771380; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 22/38 reads (58%) | catalogued as rs770970036; called by mutect2, varscan2
- AASDH | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1553933621, COSV99221109; called by muse, mutect2, varscan2
- AASS | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV100741751; called by muse, mutect2, varscan2
- ABCA10 | c.25T>A p.F9I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV99288395; called by muse, varscan2
- ABCA12 | c.5036T>C p.L1679S (on ENST00000272895 / NM_173076.3; = p.L1361S on NM_015657.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99789464; called by muse, mutect2, varscan2
- ABCA3 | c.3586A>G p.M1196V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.377); catalogued as COSV100068324; called by muse, mutect2, varscan2
- ABCA4 | c.4391C>A p.P1464H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100933105; called by muse, mutect2, varscan2
- ABCA5 | c.3364A>G p.I1122V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101201106; called by muse, mutect2, varscan2
- ABCA9 | c.3557T>C p.I1186T | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100382984; called by muse, mutect2, varscan2
- ABCA9 | c.574-2A>G p.X192_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100382986; called by muse, mutect2
- ABCB1 | c.3020A>T p.H1007L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as COSV99712733; called by muse, mutect2, varscan2
- ABCB11 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99791960; called by muse, mutect2, varscan2
- ABCC3 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762536067, COSV53317971; called by muse, mutect2, varscan2
- ABCC8 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs755181061, COSV56857996; called by mutect2, varscan2
- ABCC9 | c.4070T>C p.L1357P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99685388; called by muse, mutect2, varscan2
- ABHD11 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99766785; called by muse, mutect2, varscan2
- ABHD12 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100194350; called by muse, mutect2, varscan2
- ABHD16A | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101013178, COSV65451408; called by muse, mutect2, varscan2
- ABI3BP | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV99426218; called by muse, mutect2, varscan2
- ABL1 | c.2351C>A p.P784H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100583231, COSV100583805; called by muse, mutect2, varscan2
- ABLIM2 | c.347T>C p.F116S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs757642739, COSV56405154; called by muse, mutect2, varscan2
- ABR | c.2526del p.I843Ffs*41 (on ENST00000302538 / NM_021962.5; = p.I806Ffs*41 on NM_001092.5) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs750897785; called by mutect2, pindel, varscan2
- ABRAXAS1 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV99788460; called by muse, mutect2, varscan2
- ABTB1 | c.753dup p.E252Rfs*5 (on ENST00000232744 / NM_172027.3; = p.E110Rfs*5 on NM_032548.3) | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs778018398; called by pindel, varscan2
- ABTB2 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV100131075; called by muse, mutect2, varscan2
- AC004832.3 | c.871_872insA p.L291Hfs*24 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as COSV99840807; called by mutect2, pindel, varscan2
- AC006059.2 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100045424; called by muse, mutect2, varscan2
- AC098582.1 | c.2926C>A p.L976M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99985492; called by muse, mutect2, varscan2
- ACADL | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52053808; called by muse, mutect2, varscan2
- ACAN | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV100717753, COSV100719431; called by muse, mutect2, varscan2
- ACAN | c.7206G>T p.Q2402H (on ENST00000560601 / NM_001369268.1; = p.Q2326H on NM_001135.3) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100717758; called by muse, varscan2
- ACBD4 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100416156; called by muse, mutect2, varscan2
- ACOT2 | c.809T>C p.F270S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99468951; called by muse, mutect2, varscan2
- ACOX2 | c.475+1G>A p.X159_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100250113; called by muse, varscan2
- ACOX2 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100250114; called by muse, varscan2
- ACOX3 | c.599T>C p.M200T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs35423403, COSV100711931; called by muse, mutect2, varscan2
- ACSL1 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.427); catalogued as rs774970320, COSV99860551; called by muse, mutect2, varscan2
- ACSL5 | c.1789G>A p.A597T (on ENST00000354273; = p.A653T on NM_016234.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV100634554; called by muse, mutect2, varscan2
- ACSM1 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99532594; called by muse, mutect2, varscan2
- ACTBL2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.591); catalogued as rs1000719305, COSV101379436, COSV70661270; called by muse, mutect2, varscan2
- ACTL7A | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs751148362, COSV61776863; called by mutect2, varscan2
- ACTN1 | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as COSV51996817; called by muse, mutect2, varscan2
- ACTRT2 | c.911dup p.T305Hfs*9 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | catalogued as rs777174619; called by mutect2, pindel, varscan2
- ACVR1B | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748742473, COSV99231402; called by muse, mutect2, varscan2
- ACVR1B | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); catalogued as rs751308109, COSV99231183; called by mutect2, varscan2
- ADAM17 | c.1915-1G>T p.X639_splice | Splice Site (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100176190; called by muse, mutect2, varscan2
- ADAM22 | c.1788G>T p.R596= | Splice Region (SNP) | VAF 15/41 reads (37%) | catalogued as rs1368683700, COSV99716476; called by muse, mutect2, varscan2
- ADAM32 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765979175, COSV101165360; called by muse, varscan2
- ADAMTS1 | c.2602A>G p.K868E | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.474); catalogued as COSV99536042; called by muse, mutect2, varscan2
- ADAMTS1 | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99536044; called by muse, mutect2, varscan2
- ADAMTS12 | c.4030A>G p.M1344V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100710694; called by muse, mutect2, varscan2
- ADAMTS13 | c.3494G>A p.R1165Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs139286990; called by muse, mutect2, varscan2
- ADAMTS16 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs1283243788, COSV56980321; called by muse, mutect2, varscan2
- ADAMTS17 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV99170506; called by muse, mutect2, varscan2
- ADAMTS20 | c.5643G>T p.E1881D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as COSV101239133; called by muse, mutect2, varscan2
- ADAMTS20 | c.3985G>A p.V1329M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101166207; called by muse, mutect2, varscan2
- ADAMTS7 | c.1594T>G p.F532V | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV101183081; called by muse, mutect2, varscan2
- ADAMTS7 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as COSV101183082; called by muse, mutect2
- ADAMTSL3 | c.3627G>T p.E1209D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.185); catalogued as COSV99718170; called by muse, mutect2, varscan2
- ADCY2 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as COSV100602539; called by muse, mutect2, varscan2
- ADCY2 | c.1855A>T p.I619F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as COSV100602541; called by muse, mutect2, varscan2
- ADCY4 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs750000650, COSV60251740; called by mutect2, varscan2
- ADCY5 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101518422; called by muse, mutect2, varscan2
- ADCY7 | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs775962958, COSV54268855; called by muse, varscan2
- ADGRA3 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.852); catalogued as rs1393588101, COSV99293181; called by muse, mutect2, varscan2
- ADGRB1 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV100029514; called by muse, mutect2, varscan2
- ADGRB1 | c.2852T>C p.L951P | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100029518; called by muse, mutect2, varscan2
- ADGRB2 | c.286dup p.R96Pfs*18 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs1432907014; called by mutect2, pindel, varscan2
- ADGRB3 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101000317; called by muse, varscan2
- ADGRD1 | c.1921T>C p.Y641H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99894938; called by muse, mutect2, varscan2
- ADGRE1 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51681509; called by muse, mutect2, varscan2
- ADGRF1 | c.1801A>G p.I601V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51947642, COSV99347181; called by muse, mutect2, varscan2
- ADGRG2 | c.1021G>A p.V341M (on ENST00000379869 / NM_001079858.3; = p.V338M on NM_005756.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs778257924, COSV100492149; called by muse, mutect2, varscan2
- ADGRL3 | c.1734G>T p.K578N (on ENST00000506720 / NM_001322402.2; = p.K510N on NM_015236.6) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.3); catalogued as COSV72231139; called by muse, mutect2, varscan2
- ADGRV1 | c.14128A>C p.S4710R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101315765; called by mutect2, varscan2
- ADHFE1 | c.96A>C p.Q32H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV99397758; called by muse, mutect2, varscan2
- ADIPOR1 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100579474; called by muse, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.048); catalogued as COSV100823705; called by muse, mutect2, varscan2
- ADPRHL1 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100733410; called by muse, mutect2
- ADRA2B | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs367910193; called by muse, mutect2, varscan2
- ADRM1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.869); catalogued as rs1487315561, COSV99439343; called by muse, mutect2, varscan2
- AEBP1 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99788673; called by muse, mutect2, varscan2
- AFF1 | c.2904G>A p.M968I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100320406; called by muse, mutect2, varscan2
- AFF2 | c.1263G>A p.S421= | Splice Region (SNP) | VAF 7/57 reads (12%) | catalogued as rs1269465509, COSV54007225; called by muse, mutect2, varscan2
- AFF3 | c.2167G>A p.V723I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV100418575; called by muse, mutect2, varscan2
- AFG1L | c.749-1G>T p.X250_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100933928; called by muse, mutect2, varscan2
- AGAP2 | c.1280T>C p.L427P (on ENST00000547588 / NM_001122772.2; = p.L91P on NM_014770.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99222843; called by muse, mutect2, varscan2
- AGAP3 | c.758G>A p.R253Q (on ENST00000622464; = p.R289Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs754272615, COSV100103734; called by muse, mutect2, varscan2
- AGAP6 | c.320C>T p.T107I (on ENST00000374056 / NM_001365867.1; = p.T130I on NM_001077665.2) | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV100929076; called by muse, varscan2
- AGFG1 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV100028587; called by muse, mutect2
- AGT | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs61757175, COSV100794319; called by mutect2, varscan2
- AHDC1 | c.3714G>T p.K1238N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99899161; called by muse, mutect2, varscan2
- AHDC1 | c.3076G>A p.G1026R | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs774950354, COSV99899166; called by muse, mutect2, varscan2
- AHDC1 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99899168; called by muse, mutect2, varscan2
- AHNAK | c.14008C>T p.P4670S | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99946898; called by muse, mutect2, varscan2
- AHNAK2 | c.13047G>C p.Q4349H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100316973; called by muse, mutect2, varscan2
- AHNAK2 | c.6802C>T p.P2268S | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.79); catalogued as COSV100316975; called by muse, mutect2, varscan2
- AICDA | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1443242132, COSV99984111; called by muse, mutect2, varscan2
- AIFM1 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99780942; called by muse, mutect2, varscan2
- AIG1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as rs1423551061, COSV99263602; called by muse, mutect2
- AIM2 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV100931055; called by muse, mutect2, varscan2
- AK4 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs756118638, COSV59197633; called by muse, mutect2, varscan2
- AKAP11 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV99213796; called by muse, mutect2
- AKAP11 | c.3253G>A p.V1085M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV99213797; called by muse, mutect2, varscan2
- AKAP6 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99800046; called by muse, mutect2, varscan2
- AKAP7 | c.940C>T p.Q314* (on ENST00000431975 / NM_016377.4; = p.Q47* on NM_004842.4) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99541424; called by muse, mutect2
- AKAP9 | c.11352G>T p.K3784N (on ENST00000359028; = p.K3760N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100662282; called by muse, mutect2, varscan2
- AKT1S1 | c.464G>A p.S155N (on ENST00000344175 / NM_001098633.4; = p.S175N on NM_032375.5) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100465123; called by muse, mutect2, varscan2
- AL121899.2 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199889633; called by muse, mutect2, varscan2
- AL441992.2 | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100223485; called by muse, mutect2, varscan2
- AL592490.1 | c.2073G>T p.K691N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV101308146; called by muse, mutect2, varscan2
- AL592490.1 | c.1890G>T p.L630F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101308147, COSV69427763; called by muse, mutect2, varscan2
- AL592490.1 | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775461478, COSV101308148; called by mutect2, varscan2
- ALB | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV55738030, COSV99891225; called by mutect2, varscan2
- ALDH18A1 | c.481T>C p.C161R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100973142; called by muse, mutect2, varscan2
- ALDH3B1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.836); catalogued as COSV99141807; called by muse, mutect2, varscan2
- ALDH7A1 | c.915C>A p.A305= | Splice Region (SNP) | VAF 3/22 reads (14%) | catalogued as COSV101302005; called by muse, mutect2
- ALG13 | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99321999; called by muse, mutect2, varscan2
- ALG13 | c.2627C>T p.T876I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99322005; called by muse, mutect2, varscan2
- ALK | c.4609G>A p.G1537R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs958335893, COSV66581376; called by muse, mutect2, varscan2
- ALK | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101201823; called by mutect2, varscan2
- ALK | c.474del p.E160Rfs*26 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as rs1244823020; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ALMS1 | c.8654G>A p.R2885Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs185447739, COSV100042067, COSV52505265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15B | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs967819297, COSV101205599; called by muse, varscan2
- ALOX5 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100980043; called by muse, mutect2, varscan2
- ALPK3 | c.3199A>G p.S1067G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV99360682; called by muse, mutect2, varscan2
- AMER3 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as COSV100366361; called by muse, mutect2, varscan2
- AMHR2 | c.650T>G p.V217G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99143153; called by muse, mutect2, varscan2
- AMHR2 | c.1622T>C p.I541T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99143155; called by muse, varscan2
- AMHR2 | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as COSV57685061, COSV99143158; called by muse, varscan2
- AMIGO1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100881019; called by muse, mutect2, varscan2
- AMIGO3 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100246537; called by muse, mutect2, varscan2
- AMPD2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99857619; called by muse, mutect2, varscan2
- ANAPC5 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as COSV99946123; called by muse, mutect2, varscan2
- ANGPT1 | c.704A>G p.K235R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV52433761; called by muse, mutect2, varscan2
- ANGPT1 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.323); catalogued as COSV99861869, COSV99862567; called by muse, mutect2, varscan2
- ANK1 | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs1188118509, COSV99224835; called by muse, mutect2, varscan2
- ANK2 | c.5204A>G p.E1735G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV100000970; called by muse, mutect2
- ANK2 | c.10349C>T p.T3450I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.146); catalogued as COSV100000972; called by muse, mutect2, varscan2
- ANKFY1 | c.2989G>A p.V997M (on ENST00000341657 / NM_001330063.2; = p.V998M on NM_016376.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100492548; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4218T>A p.C1406* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99782892; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.5080G>A p.V1694I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51856303; called by muse, mutect2, varscan2
- ANKRA2 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99706999; called by muse, mutect2, varscan2
- ANKRD12 | c.2060G>T p.R687M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100041105; called by muse, mutect2, varscan2
- ANKRD13B | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV101198889; called by muse, varscan2
- ANKRD13B | c.351del p.V118Cfs*16 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | catalogued as COSV101198891; called by pindel, varscan2
- ANKRD13C | c.842del p.F281Sfs*12 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV99257617; called by mutect2, pindel, varscan2
- ANKRD17 | c.6714T>A p.N2238K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV100428941; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD26 | c.2375G>T p.R792I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV101063120; called by muse, mutect2
- ANKRD26 | c.2037G>T p.Q679H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65773982, COSV65776981; called by muse, mutect2, varscan2
- ANKRD27 | c.1538T>A p.L513Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60129311; called by muse, mutect2, varscan2
- ANKRD27 | c.1510T>C p.C504R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100042717; called by muse, mutect2, varscan2
- ANKRD28 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV101080563; called by muse, mutect2, varscan2
- ANKRD34B | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100103493; called by muse, mutect2, varscan2
- ANKRD50 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101538930; called by muse, mutect2, varscan2
- ANKS1A | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100832280, COSV64465866; called by muse, varscan2
- ANKS1B | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV101612675; called by muse, mutect2, varscan2
- ANKS1B | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV101612645; called by muse, mutect2, varscan2
- ANKS1B | c.133A>C p.S45R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101612676; called by muse, mutect2, varscan2
- ANO7 | c.2137C>A p.L713M (on ENST00000274979; = p.L659M on NM_001370694.2) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV99238064; called by muse, mutect2, varscan2
- ANPEP | c.1824G>T p.Q608H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as COSV100262928; called by muse, mutect2, varscan2
- ANXA4 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV101268791; called by muse, mutect2, varscan2
- AOC2 | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99520101; called by muse, mutect2, varscan2
- AP001781.2 | c.465dup p.L156Afs*12 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | catalogued as rs781784423; called by mutect2, varscan2
- AP1G1 | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100250313; called by muse, mutect2, varscan2
- AP1M1 | c.1272A>G p.*424Wext*86 | Nonstop Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99358334; called by muse, mutect2, varscan2
- AP2M1 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1268508290, COSV99490508, COSV99490547; called by muse, mutect2, varscan2
- AP3B1 | c.2779G>T p.G927C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV99671126; called by muse, mutect2, varscan2
- AP3B1 | c.1257A>T p.Q419H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV99671128; called by muse, mutect2, varscan2
- AP3B2 | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1468716786, COSV99916327; called by muse, mutect2, varscan2
- AP3M1 | c.1037T>A p.I346N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53008078; called by muse, mutect2
- AP3S2 | c.348G>A p.V116= | Splice Region (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100318463; called by muse, mutect2, varscan2
- APAF1 | c.2741T>C p.V914A (on ENST00000551964 / NM_181861.2; = p.V860A on NM_001160.3) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.13); catalogued as rs759075433, COSV100452459; called by muse, mutect2, varscan2
- APCDD1 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100789941; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs546686089; called by mutect2, varscan2
- APLNR | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as rs1446138644, COSV99951388; called by muse, mutect2, varscan2
- APLNR | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99951392; called by mutect2, varscan2
- APLP1 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV55705525; called by muse, mutect2, varscan2
- APOB | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV99265048; called by muse, mutect2, varscan2
- APOBEC1 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs199895916, COSV99981069; called by muse, mutect2, varscan2
- APOO | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100447981; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | catalogued as rs749401724; called by mutect2, varscan2
- APPL1 | c.1501T>A p.L501I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV55702511, COSV99897591; called by muse, mutect2, varscan2
- AQP12B | c.317A>G p.Q106R (on ENST00000621682; = p.Q118R on NM_001102467.2) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV101315865; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- ARFGEF2 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs774856463, COSV100904210; called by muse, mutect2, varscan2
- ARFGEF2 | c.4805T>C p.M1602T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100904211; called by muse, mutect2, varscan2
- ARFGEF3 | c.4922G>A p.C1641Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99293131; called by muse, mutect2, varscan2
- ARHGAP30 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100920209; called by muse, mutect2, varscan2
- ARHGAP32 | c.5493T>A p.H1831Q (on ENST00000310343 / NM_001378025.1; = p.H1482Q on NM_014715.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.502); catalogued as COSV100087527; called by muse, mutect2, varscan2
- ARHGAP32 | c.3779C>T p.T1260I (on ENST00000310343 / NM_001378025.1; = p.T911I on NM_014715.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as COSV100087531; called by muse, mutect2, varscan2
- ARHGAP33 | c.2630G>T p.R877M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV50236663, COSV99137941; called by muse, mutect2, varscan2
- ARHGAP35 | c.2914dup p.R972Pfs*40 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs1365296949; called by mutect2, varscan2
- ARHGAP44 | c.1779G>T p.K593N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99310510; called by muse, mutect2, varscan2
- ARHGAP45 | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV100490609; called by muse, mutect2, varscan2
- ARHGEF1 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100528951; called by mutect2, varscan2
- ARHGEF1 | c.745-2A>G p.X249_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100528952; called by muse, mutect2
- ARHGEF1 | c.2183T>C p.L728P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100528953; called by muse, varscan2
- ARHGEF15 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100730029; called by muse, mutect2, varscan2
- ARHGEF17 | c.1538C>A p.P513H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.04); catalogued as COSV55232878, COSV99735348; called by muse, varscan2
- ARHGEF17 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99735352; called by muse, varscan2
- ARHGEF17 | c.3270+1G>A p.X1090_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99735357; called by muse, mutect2, varscan2
- ARHGEF17 | c.4007C>T p.T1336M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs879597527, COSV99735358; called by muse, mutect2, varscan2
- ARHGEF18 | c.3134G>A p.R1045H (on ENST00000359920 / NM_001130955.2; = p.R941H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs145300154; called by muse, mutect2, varscan2
- ARHGEF4 | c.1805C>A p.A602D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.589); catalogued as COSV100387922; called by muse, mutect2, varscan2
- ARHGEF9 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99491656; called by muse, mutect2, varscan2
- ARID1B | c.5924G>T p.R1975I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268555; called by muse, varscan2
- ARID2 | c.5011G>T p.G1671C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100535944; called by muse, mutect2
- ARID3A | c.1663G>A p.G555S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs572708769, COSV55043308; called by muse, mutect2, varscan2
- ARID3B | c.1634C>T p.T545I (on ENST00000622429 / NM_001307939.1; = p.T544I on NM_006465.4) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100654600; called by muse, mutect2, varscan2
- ARID5A | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV100673574, COSV62590778; called by muse, mutect2, varscan2
- ARL2 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV99880550; called by muse, mutect2, varscan2
- ARMH4 | c.2096G>T p.S699I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50761652; called by muse, mutect2, varscan2
- ARNT2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100308866; called by muse, mutect2, varscan2
- ARNTL2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs770182082, COSV99667684; called by muse, mutect2, varscan2
- ARSB | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs200364654, COSV99364622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARSD | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99472091; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 7/14 reads (50%) | catalogued as rs753865255; called by mutect2, varscan2
- ART5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99167153; called by muse, mutect2, varscan2
- ARVCF | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs775972411, COSV99599141; called by muse, mutect2, varscan2
- ASAP3 | c.2154G>T p.Q718H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100369367; called by muse, mutect2, varscan2
- ASB12 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.216); catalogued as COSV100744681; called by muse, mutect2, varscan2
- ASB15 | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as COSV99306427; called by muse, mutect2
- ASB3 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.586); catalogued as COSV99711920; called by muse, varscan2
- ASB3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99711922; called by muse, varscan2
- ASCC2 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100316195, COSV57075264; called by muse, mutect2, varscan2
- ASCC3 | c.801+2T>C p.X267_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV61231150; called by muse, mutect2, varscan2
- ASIC1 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1287483556, COSV99948009; called by muse, mutect2, varscan2
- ASIC3 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV99874216; called by muse, mutect2, varscan2
- ASIC5 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV101539731; called by muse, mutect2, varscan2
- ASIP | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1342057552, COSV66588650; called by muse, mutect2, varscan2
- ASMTL | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as rs373167327, COSV101187738; called by muse, mutect2, varscan2
- ASMTL | c.285dup p.L96Afs*145 | Frame Shift Ins (INS) | VAF 11/97 reads (11%) | catalogued as rs756040609; called by mutect2, pindel, varscan2
- ASPSCR1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.602); catalogued as rs984947339, COSV100144807; called by muse, mutect2, varscan2
- ASTN1 | c.2673C>T p.G891= | Splice Region (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100706214; called by muse, mutect2, varscan2
- ASXL1 | c.149C>A p.T50N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100038678; called by muse, mutect2, varscan2
- ASXL1 | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV100038681; called by muse, mutect2, varscan2
- ATAD2B | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99477420; called by muse, mutect2, varscan2
- ATAD2B | c.2182A>T p.I728F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV99477424; called by muse, mutect2, varscan2
- ATAD5 | c.1336del p.I446Sfs*26 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV58976989; called by mutect2, pindel
- ATAT1 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV99527869; called by muse, mutect2
- ATCAY | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56659189; called by muse, mutect2, varscan2
- ATE1 | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816976; called by muse, mutect2, varscan2
- ATF5 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100351945; called by muse, mutect2, varscan2
- ATG2A | c.5275C>A p.Q1759K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV101034192; called by muse, varscan2
- ATG2B | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100737917; called by muse, mutect2
- ATG7 | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV100607132, COSV61615655; called by muse, mutect2, varscan2
- ATG9A | c.1920G>T p.Q640H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99521775; called by muse, mutect2, varscan2
- ATG9A | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV100772552; called by muse, mutect2, varscan2
- ATL3 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100219801; called by muse, mutect2, varscan2
- ATM | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV99589102; called by muse, mutect2
- ATP10A | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100791105; called by muse, mutect2, varscan2
- ATP10B | c.3889A>G p.T1297A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100514663; called by muse, mutect2, varscan2
- ATP10B | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100514665; called by muse, mutect2, varscan2
- ATP10D | c.2722G>A p.A908T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV99905492; called by muse, mutect2
- ATP11A | c.1992-2A>G p.X664_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99368128; called by muse, varscan2
- ATP1A2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as COSV100767762; called by muse, mutect2, varscan2
- ATP1A3 | c.3050G>T p.G1017V (on ENST00000545399 / NM_001256214.2; = p.G1004V on NM_152296.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs782204932, COSV100131852, COSV100132196; called by muse, mutect2, varscan2
- ATP1B2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs746382385, COSV100006876; called by mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATP2A3 | c.324G>T p.Q108H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM992301, COSV99989051; called by muse, varscan2
- ATP2B2 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); catalogued as rs756350386, COSV59494333; called by muse, varscan2
- ATP2B2 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.992); catalogued as COSV100659939; called by muse, varscan2
- ATP2B3 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557010945, COSV54855086; called by muse, mutect2, varscan2
- ATP2C1 | c.1890G>A p.K630= | Splice Region (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100146600; called by muse, mutect2, varscan2
- ATP6AP2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV101011481; called by muse, mutect2, varscan2
- ATP6V0A4 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100023001; called by muse, mutect2, varscan2
- ATP6V0D2 | c.360dup p.S121Ifs*32 | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | catalogued as rs752555019; called by mutect2, pindel, varscan2
- ATP6V1H | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100778629; called by muse, mutect2, varscan2
- ATP8A2 | c.3196C>A p.L1066M | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as COSV99681364; called by muse, mutect2, varscan2
- ATP8B1 | c.3473T>C p.L1158P | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99377158; called by muse, mutect2, varscan2
- ATP8B1 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99377160; called by muse, mutect2, varscan2
- ATP8B3 | c.3622C>T p.R1208* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs753155554, COSV100034322; called by muse, mutect2, varscan2
- ATRX | c.3278G>T p.R1093M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as rs1557137763, COSV64874282; called by muse, mutect2, varscan2
- ATXN7 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs767259206, COSV55753215; called by muse, mutect2, varscan2
- AUH | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769894315, CM030784, COSV57862228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AUP1 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV99239618; called by muse, mutect2, varscan2
- AURKC | c.893G>A p.R298Q (on ENST00000302804 / NM_001015878.2; = p.R264Q on NM_003160.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs575228273, COSV57140463; called by muse, mutect2, varscan2
- AVEN | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100145448; called by muse, mutect2
- AVPR1B | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs371386365; called by muse, mutect2, varscan2
- AVPR1B | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100899359; called by muse, mutect2, varscan2
- AWAT2 | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs375637323, COSV99339611; called by muse, mutect2, varscan2
- AXDND1 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as rs754952987, COSV62642121; called by mutect2, varscan2
- B3GALT2 | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV100813585; called by muse, mutect2, varscan2
- B3GNTL1 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV100301902; called by muse, mutect2, varscan2
- B4GALNT3 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99842856; called by muse, mutect2, varscan2
- B4GALT5 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV100866979; called by muse, mutect2, varscan2
- BACE1 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV57285445; called by muse, mutect2, varscan2
- BAG3 | c.778_779insA p.L260Hfs*59 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as COSV100958217; called by mutect2, pindel, varscan2
- BAG6 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99276855; called by muse, mutect2, varscan2
- BAHCC1 | c.3130C>T p.Q1044* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100311488; called by muse, mutect2, varscan2
- BAHCC1 | c.4714G>A p.V1572M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs1215510398, COSV100311489; called by muse, mutect2, varscan2
- BAHCC1 | c.5510T>C p.L1837P | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs1265098539, COSV100311491; called by muse, mutect2, varscan2
- BAZ2B | c.5726C>T p.A1909V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100600549; called by muse, varscan2
- BBS12 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.382); catalogued as COSV100044903; called by muse, mutect2, varscan2
- BCAN | c.1286G>T p.R429M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV100228029; called by muse, mutect2, varscan2
- BCKDK | c.686_688del p.K229del | In Frame Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs1567429126; called by pindel, varscan2
- BCL2L12 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.628); catalogued as COSV99881027; called by muse, mutect2, varscan2
- BCL2L15 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs760620431, COSV100851578; called by muse, mutect2, varscan2
- BCL3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99378082; called by muse, mutect2, varscan2
- BCO1 | c.668G>A p.C223Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs764128777, COSV99257771; called by muse, varscan2
- BCORL1 | c.3476C>T p.T1159I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV54393354; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs768244116; called by mutect2, varscan2
- BEGAIN | c.1558del p.D520Tfs*57 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as rs749168305; called by mutect2, varscan2
- BEND7 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs534620750, COSV100346581; called by muse, mutect2, varscan2
- BICC1 | c.1610C>T p.T537I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs752282661, COSV99570429; called by muse, mutect2, varscan2
- BICRAL | c.3128C>A p.P1043H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as rs866199154, COSV100018004; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BIRC6 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV101427932, COSV101428142; called by muse, mutect2, varscan2
- BIRC6 | c.2297T>C p.L766S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV101427995, COSV101428143; called by muse, mutect2, varscan2
- BIRC6 | c.6544G>A p.V2182M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748895437, COSV101428144; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as rs1374580761, COSV100863719; called by muse, mutect2, varscan2
- BMP2K | c.3168del p.N1057Mfs*32 | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | catalogued as COSV55008554; called by mutect2, pindel, varscan2
- BMP7 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755997469, COSV101215859; called by mutect2, varscan2
- BMPR1A | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100923451; called by muse, varscan2
- BMX | c.1379A>G p.E460G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564414; called by muse, mutect2, varscan2
- BNC1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100597116, COSV61757588; called by muse, mutect2, varscan2
- BNC2 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66151137; called by muse, mutect2, varscan2
- BNIP1 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99199384; called by muse, mutect2, varscan2
- BPI | c.1321C>T p.P441S (on ENST00000262865; = p.P437S on NM_001725.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1170296003, COSV53406197, COSV99480559; called by muse, mutect2, varscan2
- BPIFA1 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV100845636; called by muse, mutect2, varscan2
- BPIFB4 | c.1546A>T p.T516S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.814); catalogued as COSV100971493; called by muse, mutect2, varscan2
- BRAT1 | c.566del p.G189Vfs*30 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as rs1384976053; called by mutect2, pindel, varscan2
- BRD3 | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100324939; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV99650358; called by muse, mutect2, varscan2
- BRD9 | c.1139-1G>A p.X380_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100057125; called by muse, mutect2, varscan2
- BRI3BP | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs752859936, COSV100413002; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2
- BRWD1 | c.3980A>G p.N1327S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1262002119; called by muse, mutect2
- BRWD3 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100955933, COSV64753335; called by muse, mutect2, varscan2
- BSN | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV99608060; called by muse, mutect2, varscan2
- BSN | c.8869A>G p.K2957E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs781244358, COSV99608062; called by muse, mutect2, varscan2
- BSPRY | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99444890; called by mutect2, varscan2
- BST1 | c.789C>T p.Y263= | Splice Region (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99399874; called by muse, mutect2, varscan2
- BTBD1 | c.1056-2A>G p.X352_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99915406; called by mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD6 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100527182; called by muse, mutect2, varscan2
- BTBD9 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100021568; called by muse, mutect2, varscan2
- BTN2A2 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV100760348; called by muse, mutect2, varscan2
- C10orf53 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as rs1160167847, COSV100935037; called by muse, mutect2, varscan2
- C10orf71 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs938833598, COSV60506898; called by muse, mutect2, varscan2
- C11orf24 | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100422542; called by muse, mutect2, varscan2
- C12orf42 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59384692, COSV59387329; called by muse, mutect2, varscan2
- C16orf46 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV100215250; called by muse, mutect2, varscan2
- C16orf54 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs982919079, COSV100268445; called by muse, mutect2, varscan2
- C16orf71 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54787673; called by muse, mutect2, varscan2
- C16orf89 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs1242333739, COSV100280795; called by mutect2, varscan2
- C17orf80 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99277980; called by muse, mutect2, varscan2
- C19orf12 | c.210dup p.L71Afs*12 (on ENST00000392278 / NM_001031726.3; = p.L60Afs*12 on NM_031448.6) | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | catalogued as rs770374870; called by mutect2, pindel, varscan2
- C19orf12 | c.83G>T p.G28V (on ENST00000392278 / NM_001031726.3; = p.G17V on NM_031448.6) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV100080536; called by muse, mutect2, varscan2
- C1QTNF9B | c.364G>T p.G122W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101158564; called by muse, mutect2, varscan2
- C1orf158 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99847276; called by muse, mutect2, varscan2
- C1orf74 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99160961; called by muse, mutect2, varscan2
- C1orf87 | c.1580G>T p.R527I | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100967012; called by muse, mutect2, varscan2
- C1orf87 | c.1480G>T p.G494* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100967016; called by muse, mutect2, varscan2
- C1orf94 | c.1465G>A p.A489T (on ENST00000488417 / NM_001134734.2; = p.A299T on NM_032884.5) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV100974826; called by muse, mutect2, varscan2
- C20orf27 | c.439A>G p.T147A (on ENST00000379772 / NM_001258429.2; = p.T172A on NM_001039140.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV99422153; called by muse, mutect2, varscan2
- C2CD6 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99632598; called by muse, mutect2, varscan2
- C2orf16 | c.5519G>T p.R1840M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.227); catalogued as COSV100820751; called by muse, mutect2, varscan2
- C2orf78 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV101280952; called by muse, mutect2, varscan2
- C3 | c.4910G>A p.C1637Y | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55573078, COSV99836490; called by muse, mutect2, varscan2
- C3orf20 | c.2588T>C p.L863P | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99513735; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C3orf38 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100007383; called by muse, mutect2, varscan2
- C3orf56 | c.138C>A p.C46* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV101228946; called by muse, mutect2
- C5 | c.2998C>A p.L1000I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99797656; called by muse, mutect2, varscan2
- C5 | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56327616, COSV99797658; called by muse, mutect2, varscan2
- C5AR1 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100753997; called by muse, mutect2, varscan2
- C5AR1 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100754000; called by muse, mutect2, varscan2
- C6orf58 | c.622T>C p.W208R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs900653896, COSV100314831; called by muse, mutect2, varscan2
- C7orf26 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100732871, COSV100732950; called by mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 28/46 reads (61%) | catalogued as rs747591930; called by mutect2, varscan2
- C8orf34 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100445809, COSV61381992; called by muse, mutect2
- C9 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs1044402484, COSV54678302, COSV99661963; called by muse, mutect2, varscan2
- C9orf131 | c.1117G>T p.G373* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100398038; called by muse, mutect2, varscan2
- C9orf131 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777411018, COSV100398040; called by muse, mutect2, varscan2
- C9orf131 | c.2624A>G p.Q875R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV100398046; called by muse, mutect2, varscan2
- C9orf78 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs139248631, COSV100989965; called by muse, mutect2, varscan2
- CA13 | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100410136; called by muse, mutect2, varscan2
- CA8 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100526829; called by muse, mutect2, varscan2
- CABCOCO1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100357825; called by mutect2, varscan2
- CABIN1 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772175109, COSV99573059; called by muse, mutect2, varscan2
- CACHD1 | c.2494G>A p.G832S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV99261999; called by muse, mutect2, varscan2
- CACNA1B | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99496711; called by muse, mutect2, varscan2
- CACNA1E | c.1549G>T p.G517* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100702073; called by muse, mutect2, varscan2
- CACNA1G | c.1907T>G p.L636R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV100661664; called by muse, mutect2, varscan2
- CACNA1I | c.2803dup p.R935Pfs*29 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs751819797; called by mutect2, pindel, varscan2
- CACNA1S | c.4743G>T p.E1581D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV62936638; called by muse, mutect2, varscan2
- CACNA2D1 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV100666441; called by muse, mutect2, varscan2
- CACNA2D2 | c.1673T>C p.V558A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99817418; called by muse, mutect2
- CACNA2D4 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs1555188219, COSV99765465, COSV99765814; called by muse, mutect2, varscan2
- CACNG6 | c.640A>G p.T214A (on ENST00000252729 / NM_145814.1; = p.T143A on NM_031897.2) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV53165933; called by muse, mutect2, varscan2
- CAD | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV99254886; called by muse, mutect2, varscan2
- CADM1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV100522498; called by muse, mutect2, varscan2
- CADPS | c.3882G>T p.K1294N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99337403; called by muse, mutect2, varscan2
- CADPS2 | c.1043T>C p.I348T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV100462219; called by muse, mutect2
- CALML3 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100178792; called by muse, mutect2, varscan2
- CALR | c.1054-2A>C p.X352_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100330597; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006dup p.R336Pfs*4 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | catalogued as rs754747174; called by pindel, varscan2
- CAMTA2 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100772562; called by muse, mutect2, varscan2
- CAND2 | c.2764C>A p.L922M (on ENST00000456430 / NM_001162499.2; = p.L829M on NM_012298.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV99928954; called by muse, mutect2, varscan2
- CAP1 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as rs766562094, COSV100472203; called by muse, mutect2, varscan2
- CAPG | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99809370; called by muse, mutect2, varscan2
- CAPN10 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); catalogued as COSV99550160; called by muse, mutect2, varscan2
- CAPN12 | c.853T>C p.W285R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100185160; called by muse, mutect2, varscan2
- CAPN15 | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.057); catalogued as rs781378615, COSV99562383; called by muse, mutect2, varscan2
- CAPN5 | c.723G>T p.E241D (on ENST00000456580; = p.E201D on NM_004055.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV99582023; called by muse, mutect2, varscan2
- CAPN6 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100136822; called by muse, mutect2, varscan2
- CAPRIN1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100403763; called by muse, mutect2, varscan2
- CAPRIN1 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100403767, COSV58220917; called by muse, mutect2, varscan2
- CAPRIN2 | c.892+1G>A p.X298_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99195474; called by muse, mutect2
- CARD10 | c.1823dup p.G609Rfs*109 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs1266428698; called by mutect2, pindel, varscan2
- CARD6 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99620645; called by muse, mutect2, varscan2
- CARD6 | c.2696T>C p.F899S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99620647; called by muse, mutect2, varscan2
- CARD9 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100261120; called by muse, mutect2, varscan2
- CARS1 | c.1669-1G>T p.X557_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99542524; called by muse, mutect2, varscan2
- CASKIN2 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs758823462, COSV100050322; called by muse, mutect2, varscan2
- CASP8AP2 | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99386968; called by muse, mutect2, varscan2
- CASR | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99948818; called by muse, mutect2, varscan2
- CASS4 | c.1622A>T p.N541I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100824631; called by muse, mutect2, varscan2
- CATSPERG | c.2596C>A p.L866M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.134); catalogued as COSV99286366; called by muse, mutect2, varscan2
- CBFA2T3 | c.137G>T p.R46M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as COSV99241559; called by muse, mutect2, varscan2
- CBLIF | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99950864; called by muse, mutect2
- CBLN4 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99290466, COSV99290798; called by muse, mutect2
- CBX1 | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV99848111; called by muse, mutect2, varscan2
- CBX4 | c.983G>T p.R328M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.19); catalogued as COSV99490295; called by muse, mutect2, varscan2
- CCDC106 | c.596T>C p.M199T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100454206; called by muse, mutect2, varscan2
- CCDC142 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs919704180, COSV99282106; called by muse, mutect2, varscan2
- CCDC158 | c.610dup p.I204Nfs*3 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs1248476350; called by mutect2, varscan2
- CCDC167 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138745679; called by mutect2, varscan2
- CCDC172 | c.446G>T p.S149I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV100319723, COSV60937783; called by muse, mutect2, varscan2
- CCDC173 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101352356; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC180 | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100826649; called by muse, mutect2, varscan2
- CCDC22 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100873127; called by muse, mutect2, varscan2
- CCDC28A | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs750649147, COSV60425443; called by muse, mutect2, varscan2
- CCDC38 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs11108315; called by muse, mutect2, varscan2
- CCDC57 | c.2712G>C p.R904S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV60756712; called by muse, mutect2, varscan2
- CCDC69 | c.41del p.P14Rfs*21 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as rs757993279, COSV100815183; called by mutect2, pindel, varscan2
- CCDC85A | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101339352; called by muse, mutect2, varscan2
- CCDC85A | c.1657A>T p.M553L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.321); catalogued as COSV101339451; called by muse, mutect2, varscan2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 12/61 reads (20%) | catalogued as rs768846308; called by pindel, varscan2
- CCDC88A | c.2782T>A p.L928I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99710240; called by muse, mutect2, varscan2
- CCL19 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100323147; called by muse, mutect2, varscan2
- CCL26 | c.124_125insA p.L42Hfs*10 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | catalogued as COSV99139134; called by mutect2, pindel, varscan2
- CCL5 | c.5A>G p.K2R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1292018970; called by muse, mutect2, varscan2
- CCNB3 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99328843; called by muse, mutect2
- CCNE1 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV99388330; called by muse, mutect2, varscan2
- CCNE1 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99388332; called by muse, mutect2, varscan2
- CCNI | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99423346; called by muse, varscan2
- CCNT2 | c.1853G>T p.R618M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99750523; called by muse, mutect2, varscan2
- CCR3 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100656450, COSV62464992; called by muse, mutect2, varscan2
- CCT5 | c.763T>A p.F255I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725257; called by muse, mutect2, varscan2
- CD19 | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV100218088; called by muse, mutect2
- CD1D | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV100939583; called by muse, mutect2, varscan2
- CD226 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99711024; called by muse, mutect2, varscan2
- CD300LG | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.36); catalogued as COSV99517370; called by muse, mutect2, varscan2
- CD33 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as COSV99220306; called by muse, mutect2, varscan2
- CD5L | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV63821029, COSV63822188; called by mutect2, varscan2
- CD6 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100532944; called by muse, mutect2, varscan2
- CD6 | c.1418del p.P473Rfs*27 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as COSV57837143; called by mutect2, pindel, varscan2
- CD68 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1180698913, COSV99548879; called by muse, mutect2
- CD82 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV99907510; called by muse, mutect2, varscan2
- CD93 | c.308A>T p.K103M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99849109; called by muse, mutect2
- CDC27 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV99294640; called by muse, mutect2, varscan2
- CDC42EP3 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99767835; called by muse, mutect2, varscan2
- CDH10 | c.1655dup p.N552Kfs*5 | Frame Shift Ins (INS) | VAF 4/19 reads (21%) | catalogued as rs754722288; called by mutect2, pindel
- CDH23 | c.7792C>A p.L2598M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.73); catalogued as COSV99820325; called by muse, mutect2
- CDH3 | c.2276T>C p.I759T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99868053; called by muse, mutect2
- CDH6 | c.1823C>A p.P608H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99418759; called by muse, varscan2
- CDH9 | c.1987G>T p.G663C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143317; called by muse, mutect2, varscan2
- CDK12 | c.2864C>A p.P955H | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101420420; called by muse, mutect2, varscan2
- CDK13 | c.3571A>T p.I1191L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.019); catalogued as COSV99475386; called by muse, mutect2, varscan2
- CDK14 | c.1194G>T p.K398N (on ENST00000380050 / NM_001287135.2; = p.K380N on NM_012395.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.557); catalogued as COSV99724773; called by muse, mutect2, varscan2
- CDK3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs1424386342, COSV56906683; called by muse, mutect2, varscan2
- CDK7 | c.543del p.E182Sfs*11 | Frame Shift Del (DEL) | VAF 44/143 reads (31%) | catalogued as COSV56513040; called by mutect2, pindel, varscan2
- CDK8 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101037116; called by muse, mutect2, varscan2
- CDKL1 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53579882; called by muse, mutect2, varscan2
- CDKL2 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100276860; called by muse, mutect2, varscan2
- CDKL3 | c.785T>C p.I262T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs759947480, COSV99527781; called by muse, mutect2, varscan2
- CDS1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs759347542, COSV99880628; called by muse, mutect2, varscan2
- CDS2 | c.1205G>T p.R402I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100986055; called by muse, mutect2
- CDX4 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100999113, COSV100999124; called by muse, mutect2, varscan2
- CDX4 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100999127; called by muse, mutect2, varscan2
- CDYL | c.1475A>G p.K492R (on ENST00000328908 / NM_001368125.1; = p.K438R on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1190888463, COSV100189138; called by muse, mutect2, varscan2
- CEACAM7 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as rs782307166, COSV50072489; called by muse, mutect2, varscan2
- CEACAM8 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99747548; called by muse, mutect2, varscan2
- CEBPZ | c.504A>C p.E168D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99135503; called by muse, mutect2, varscan2
- CELF5 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99485873; called by muse, mutect2, varscan2
- CELSR1 | c.3991C>A p.L1331I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99417828; called by muse, mutect2, varscan2
- CELSR2 | c.7153G>T p.G2385C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as COSV99603613; called by muse, mutect2, varscan2
- CELSR3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs746103293, COSV99373278; called by muse, mutect2, varscan2
- CENPE | c.3742C>T p.Q1248* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99477604; called by muse, mutect2, varscan2
- CENPI | c.1826G>T p.R609I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99515276; called by muse, mutect2, varscan2
- CENPT | c.1281C>T p.V427= | Splice Region (SNP) | VAF 3/9 reads (33%) | catalogued as COSV99535000; called by muse, mutect2
- CENPV | c.481T>A p.S161T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.171); catalogued as COSV100233451; called by muse, mutect2
- CEP104 | c.2733G>T p.K911N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100986608; called by muse, mutect2, varscan2
- CEP128 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs753223975, COSV99824328; called by muse, mutect2, varscan2
- CEP135 | c.3401C>A p.S1134Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99954325; called by muse, mutect2, varscan2
- CEP170 | c.2470G>T p.G824* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100316898; called by muse, mutect2, varscan2
- CEP170B | c.3578G>A p.R1193H (on ENST00000453495; = p.R1122H on NM_015005.3) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370992679, CM137473; called by muse, mutect2, varscan2
- CEP250 | c.3583T>C p.S1195P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100698871; called by muse, mutect2, varscan2
- CEP250 | c.6281A>G p.Q2094R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV100698872; called by muse, mutect2, varscan2
- CEP290 | c.3041T>G p.L1014R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100468448; called by muse, mutect2, varscan2
- CEP350 | c.2416T>C p.Y806H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100854505, COSV62610276; called by muse, mutect2, varscan2
- CEP43 | c.173T>A p.V58D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100835596; called by muse, mutect2
- CEP57 | c.482G>T p.R161M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100334661; called by muse, mutect2, varscan2
- CEP70 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV99389056; called by muse, varscan2
- CEP70 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV99389058; called by muse, varscan2
- CEP70 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99389061; called by muse, varscan2
- CEP72 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1357013178, COSV53794221; called by muse, mutect2, varscan2
- CEP76 | c.1432T>C p.C478R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100042713; called by mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs747064410; called by mutect2, varscan2
- CERKL | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV100183534; called by muse, mutect2, varscan2
- CERS4 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs754222872, COSV52164958, COSV52165381; called by muse, mutect2, varscan2
- CERS6 | c.604A>T p.R202* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99986880; called by muse, mutect2, varscan2
- CES1 | c.1179G>T p.K393N (on ENST00000361503 / NM_001025194.2; = p.K392N on NM_001266.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as COSV62089462; called by muse, mutect2, varscan2
- CES1 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV100828631; called by muse, mutect2, varscan2
- CFAP43 | c.4758T>A p.N1586K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100829172; called by muse, mutect2, varscan2
- CFAP47 | c.4982G>A p.R1661K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100545238; called by muse, mutect2, varscan2
- CFAP47 | c.5312G>A p.C1771Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100545241; called by muse, mutect2, varscan2
- CFAP65 | c.4378C>T p.L1460F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV100444992; called by muse, mutect2, varscan2
- CFAP65 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs760496355, COSV58562117; called by muse, mutect2, varscan2
- CFAP65 | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV99838295; called by muse, mutect2, varscan2
- CFAP70 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV100160463; called by muse, mutect2, varscan2
- CFC1 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99383465, COSV99383516; called by muse, mutect2
- CFTR | c.4348T>G p.F1450V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV99135290; called by muse, mutect2, varscan2
- CHAMP1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100778778; called by muse, mutect2, varscan2
- CHD3 | c.938G>T p.S313I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.146); catalogued as COSV100391068; called by muse, mutect2, varscan2
- CHD3 | c.1189T>C p.C397R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100391069; called by muse, mutect2, varscan2
- CHD5 | c.4417C>T p.R1473W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907585802, COSV99313317; called by muse, mutect2, varscan2
- CHD6 | c.1179G>A p.E393= | Splice Region (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100498057; called by muse, mutect2, varscan2
- CHD7 | c.5276A>G p.K1759R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101418168; called by muse, mutect2, varscan2
- CHD7 | c.5631G>T p.E1877D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101418169; called by muse, mutect2, varscan2
- CHD8 | c.6046G>T p.V2016F (on ENST00000646647 / NM_001170629.2; = p.V1737F on NM_020920.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.17); catalogued as COSV100765278; called by muse, mutect2, varscan2
- CHD9 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs778119776, COSV101272072; called by muse, mutect2, varscan2
- CHERP | c.1931A>G p.N644S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.935); catalogued as rs534828961, COSV99550177; called by muse, mutect2, varscan2
- CHERP | c.569G>A p.C190Y | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV99550180; called by muse, mutect2, varscan2
- CHIA | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100588645; called by muse, mutect2, varscan2
- CHL1 | c.3419A>G p.D1140G (on ENST00000397491 / NM_001253387.1; = p.D1156G on NM_006614.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99850837; called by muse, mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 32/120 reads (27%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRM1 | c.819C>A p.S273R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV100186150; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA6 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); catalogued as COSV99373188; called by muse, mutect2, varscan2
- CHST14 | c.981G>A p.W327* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as rs147466381, COSV100086940; called by muse, varscan2
- CHST14 | c.1033dup p.R345Pfs*10 | Frame Shift Ins (INS) | VAF 19/95 reads (20%) | catalogued as rs774738190; called by pindel, varscan2
- CHST3 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.206); catalogued as COSV100910432; called by muse, mutect2, varscan2
- CHST9 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV99409996; called by muse, mutect2, varscan2
- CHUK | c.1977A>G p.T659= | Splice Region (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100957071; called by muse, mutect2
- CIB2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs761291382, COSV99363194; called by muse, mutect2, varscan2
- CIBAR1 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV100844654; called by muse, mutect2
- CILP2 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as rs866713077, COSV99364569; called by muse, mutect2, varscan2
- CILP2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as rs1568369615, COSV99364571; called by muse, mutect2, varscan2
- CIT | c.5615G>A p.R1872H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1565899289, COSV55887175; called by muse, mutect2, varscan2
- CIT | c.3641G>A p.G1214D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99949255; called by muse, mutect2, varscan2
- CIT | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99949257; called by muse, mutect2, varscan2
- CIZ1 | c.2518A>G p.T840A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as COSV99476779; called by muse, mutect2, varscan2
- CKM | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99675508; called by mutect2, varscan2
- CKMT1A | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV101376809; called by muse, mutect2, varscan2
- CKMT2 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562337; called by muse, mutect2, varscan2
- CLCA1 | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV99322220; called by muse, mutect2, varscan2
- CLCA4 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99760415; called by muse, mutect2, varscan2
- CLCN5 | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100260026; called by muse, mutect2, varscan2
- CLCN6 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100411827; called by mutect2, varscan2
- CLCN7 | c.1746del p.I583Sfs*6 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as COSV51972105; called by mutect2, pindel, varscan2
- CLCN7 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99247143; called by muse, mutect2, varscan2
- CLCNKA | c.855dup p.V286Cfs*38 | Frame Shift Ins (INS) | VAF 46/188 reads (24%) | catalogued as rs753052635; called by mutect2, pindel, varscan2
- CLCNKA | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as COSV100510013; called by muse, mutect2, varscan2
- CLCNKB | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99058384; called by mutect2, varscan2
- CLDN17 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.401); catalogued as COSV54522924, COSV99729109; called by muse, mutect2, varscan2
- CLDN7 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.409); catalogued as COSV100598110; called by muse, mutect2, varscan2
- CLEC11A | c.334C>T p.L112= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as COSV51575260, COSV99141609; called by muse, mutect2
- CLEC16A | c.2051C>A p.P684H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV101277884; called by muse, mutect2, varscan2
- CLEC4F | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99713681; called by muse, mutect2, varscan2
- CLIC3 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs1372641236, COSV100860380; called by muse, mutect2, varscan2
- CLMN | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100112307; called by muse, mutect2, varscan2
- CLN8 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100486024; called by muse, mutect2, varscan2
- CLPX | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100269432; called by muse, mutect2, varscan2
- CLSPN | c.2560C>A p.L854I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.925); catalogued as COSV99230706; called by muse, varscan2
- CLTCL1 | c.4621G>A p.A1541T (on ENST00000427926 / NM_007098.4; = p.A1484T on NM_001835.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV99310931; called by muse, mutect2
- CMTM6 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230257; called by muse, mutect2, varscan2
- CMYA5 | c.10132T>A p.S3378T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV101483992; called by muse, mutect2, varscan2
- CNBD1 | c.1263dup p.E422Rfs*3 | Frame Shift Ins (INS) | VAF 13/61 reads (21%) | catalogued as rs748250735; called by mutect2, pindel, varscan2
- CNGA2 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100323579; called by muse, mutect2, varscan2
- CNGA4 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99791950; called by muse, mutect2, varscan2
- CNIH1 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53594456; called by muse, mutect2
- CNKSR2 | c.1027A>G p.R343G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV99668140; called by muse, mutect2, varscan2
- CNOT4 | c.1531T>G p.L511V (on ENST00000315544 / NM_001190848.1; = p.L508V on NM_013316.4) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100211372; called by muse, mutect2
- CNOT9 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99813695; called by muse, mutect2
- CNTN2 | c.2499G>T p.W833C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084882; called by muse, mutect2, varscan2
- CNTNAP3 | c.3668dup p.A1224Rfs*9 | Frame Shift Ins (INS) | VAF 18/102 reads (18%) | catalogued as rs1316209651; called by mutect2, varscan2
- CNTNAP5 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs747273568, COSV101443368, COSV70486883; called by muse, mutect2, varscan2
- CNTNAP5 | c.3736G>A p.V1246M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV101443372; called by muse, mutect2, varscan2
- CNTROB | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.666); catalogued as COSV100972660; called by muse, mutect2, varscan2
- COG4 | c.1881G>T p.W627C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99850765; called by muse, mutect2, varscan2
- COG7 | c.52A>G p.N18D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100207512; called by muse, mutect2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs748995811; called by mutect2, varscan2
- COIL | c.485dup p.N162Kfs*6 | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616020; called by muse, mutect2, varscan2
- COL11A2 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV100553786; called by muse, mutect2, varscan2
- COL15A1 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV100897590; called by muse, mutect2, varscan2
- COL15A1 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66644683; called by muse, mutect2, varscan2
- COL16A1 | c.4001del p.P1334Lfs*101 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as COSV99595431; called by mutect2, pindel, varscan2
- COL19A1 | c.1133A>G p.K378R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1002694401, COSV100506050; called by muse, mutect2, varscan2
- COL1A2 | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99799338; called by muse, mutect2, varscan2
- COL1A2 | c.3922T>C p.F1308L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV99799340; called by muse, mutect2, varscan2
- COL20A1 | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100490345; called by muse, mutect2
- COL21A1 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55157025, COSV55173062; called by muse, mutect2, varscan2
- COL24A1 | c.2202G>T p.K734N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65307689; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 9/25 reads (36%) | catalogued as rs760493024; called by mutect2, varscan2
- COL26A1 | c.1189G>T p.G397C (on ENST00000313669 / NM_001278563.3; = p.G395C on NM_133457.4) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905237574; called by muse, mutect2, varscan2
- COL27A1 | c.2728-1G>T p.X910_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100620910, COSV61931107; called by muse, mutect2, varscan2
- COL27A1 | c.4880A>G p.D1627G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs537785868, COSV61930332; called by muse, mutect2, varscan2
- COL28A1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs771884981, COSV101258506; called by muse, mutect2, varscan2
- COL2A1 | c.3273+1G>A p.X1091_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100476163; called by muse, mutect2, varscan2
- COL4A2 | c.4030G>T p.G1344* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100847312; called by muse, mutect2, varscan2
- COL4A3 | c.4025C>T p.P1342L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs1487504289, COSV101170221; called by muse, mutect2, varscan2
- COL4A5 | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV60368474, COSV60374628; called by muse, mutect2, varscan2
- COL4A6 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.303); catalogued as COSV100563913; called by muse, mutect2, varscan2
- COL5A2 | c.2285G>A p.G762D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880174; called by muse, mutect2, varscan2
- COL6A2 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371640468; ClinVar: benign / uncertain significance; called by mutect2, varscan2
- COL6A3 | c.8147G>A p.G2716D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99796494, COSV99797536; called by muse, varscan2
- COL7A1 | c.8366A>G p.D2789G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99866199; called by muse, mutect2, varscan2
- COL7A1 | c.7488del p.P2498Lfs*18 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs35446026, CD167138, COSV60394611; called by mutect2, pindel, varscan2
- COLEC11 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363123; called by muse, mutect2
- COLGALT2 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201381167, COSV100730570; called by muse, mutect2
- COMMD3-BMI1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as rs1184565516, COSV100936363; called by muse, mutect2, varscan2
- COMMD8 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs769950448, COSV67500584; called by muse, mutect2, varscan2
- COPB1 | c.83del p.N28Mfs*3 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs1258568005; called by mutect2, pindel, varscan2
- COPB2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100300604; called by muse, mutect2, varscan2
- COPRS | c.142A>G p.T48A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV99911897; called by muse, mutect2, varscan2
- COQ2 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV100269960; called by muse, mutect2, varscan2
- COQ9 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780675090, COSV52647258; called by muse, mutect2, varscan2
- CORO2A | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV100673972; called by muse, mutect2
- CORO7 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99227497; called by muse, mutect2
- COX10 | c.114T>A p.H38Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as COSV99886289; called by muse, mutect2, varscan2
- CPAMD8 | c.1228G>A p.V410M (on ENST00000651564; = p.V363M on NM_015692.5) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.26); catalogued as rs527933498, COSV99359253; called by muse, mutect2, varscan2
- CPEB2 | c.2035-2A>G p.X679_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99470221; called by muse, mutect2, varscan2
- CPED1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100120491; called by mutect2, varscan2
- CPLX3 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100547655; called by muse, mutect2, varscan2
- CPNE2 | c.287T>G p.F96C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99321373; called by muse, mutect2, varscan2
- CPO | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs1166779766, COSV99786451; called by muse, mutect2, varscan2
- CRACD | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1282697985, COSV99949037; called by muse, mutect2
- CRACD | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99949038; called by muse, mutect2, varscan2
- CRADD | c.242G>A p.W81* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100257526; called by muse, mutect2, varscan2
- CRAT | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs762680274, COSV100539933; called by muse, mutect2, varscan2
- CRB1 | c.1658A>G p.K553R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV100957813; called by muse, mutect2, varscan2
- CREB1 | c.565G>T p.G189* (on ENST00000432329 / NM_134442.5; = p.G175* on NM_004379.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100783571; called by muse, mutect2, varscan2
- CREB3L2 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV100381791; called by muse, mutect2, varscan2
- CREBRF | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99755676; called by muse, mutect2
- CRELD1 | c.257+2T>C p.X86_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99925689; called by muse, mutect2
- CRIM1 | c.1610A>C p.K537T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV99753088; called by muse, mutect2, varscan2
- CRIM1 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538430878, COSV54864844; called by muse, mutect2, varscan2
- CRMP1 | c.620A>G p.Q207R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1189462087, COSV100271710; called by muse, mutect2, varscan2
- CRY2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101314575; called by muse, varscan2
- CRYBG1 | c.4135T>A p.S1379T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.622); catalogued as COSV100954446; called by muse, mutect2, varscan2
- CRYBG2 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371714588; called by muse, mutect2, varscan2
- CRYZ | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV100558550; called by muse, mutect2, varscan2
- CSDE1 | c.895T>G p.F299V (on ENST00000358528 / NM_001007553.3; = p.F268V on NM_007158.6) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV54745935, COSV99794628; called by muse, mutect2
- CSF2RA | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100817646; called by muse, mutect2, varscan2
- CSF3 | c.205-1G>T p.X69_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99842384; called by muse, mutect2, varscan2
- CSF3R | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.231); catalogued as COSV100117554; called by muse, mutect2, varscan2
- CSHL1 | c.597G>T p.K199N (on ENST00000309894 / NM_022581.3; = p.K105N on NM_001318.4) | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99367938; called by muse, mutect2, varscan2
- CSKMT | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100649089; called by muse, mutect2, varscan2
- CSMD1 | c.3964A>G p.I1322V (on ENST00000520002; = p.I1321V on NM_033225.6) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as rs1469697189, COSV100146710; called by muse, mutect2, varscan2
- CSMD2 | c.10416G>T p.M3472I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV99588829; called by muse, varscan2
- CSMD2 | c.5369C>G p.P1790R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99588830; called by muse, mutect2, varscan2
- CSMD2 | c.3805G>A p.A1269T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53885117, COSV99589716; called by muse, mutect2, varscan2
- CSMD3 | c.6760T>C p.Y2254H (on ENST00000297405 / NM_001363185.1; = p.Y2150H on NM_052900.3) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52366401; called by muse, mutect2, varscan2
- CSMD3 | c.3142C>A p.L1048I (on ENST00000297405 / NM_001363185.1; = p.L944I on NM_052900.3) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs1038971284, COSV52100311, COSV52199877, COSV52252257; called by muse, mutect2, varscan2
- CSMD3 | c.469A>G p.S157G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99831443; called by muse, mutect2, varscan2
- CSN3 | c.55-1G>T p.X19_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV59245129; called by muse, mutect2, varscan2
- CSNK1G3 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV62053903; called by muse, mutect2
- CSNK2A1 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV99424335; called by muse, mutect2, varscan2
- CSNK2A1 | c.427-1G>T p.X143_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53937885; called by muse, mutect2, varscan2
- CSPP1 | c.3290T>C p.L1097S (on ENST00000676605; = p.L1056S on NM_024790.6) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as COSV99138350; called by muse, mutect2, varscan2
- CST4 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV99463192; called by muse, mutect2, varscan2
- CST4 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.85); catalogued as COSV54150835; called by muse, mutect2, varscan2
- CST9L | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1321417948, COSV100980853; called by muse, mutect2, varscan2
- CSTF2 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100880688; called by muse, mutect2
- CSTF2T | c.1252A>T p.M418L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100484152; called by muse, mutect2, varscan2
- CTAGE6 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101417837; called by muse, mutect2, varscan2
- CTC1 | c.3156G>T p.Q1052H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100236352; called by muse, mutect2, varscan2
- CTCFL | c.755-1G>T p.X252_splice | Splice Site (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99712478; called by muse, mutect2
- CTNNA2 | c.2684G>T p.G895V (on ENST00000402739 / NM_001282597.3; = p.G847V on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100560085; called by muse, mutect2, varscan2
- CTNNA3 | c.1377T>C p.I459= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101048460; called by muse, mutect2
- CTNNB1 | c.2285T>C p.L762P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV62689732; called by mutect2, varscan2
- CTNND2 | c.2770A>G p.R924G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100475087; called by muse, mutect2, varscan2
- CTR9 | c.1725T>G p.H575Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV100797337; called by muse, mutect2
- CTSC | c.1147T>C p.Y383H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99910623; called by muse, mutect2, varscan2
- CTSW | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs201554107, COSV100327283; called by muse, mutect2, varscan2
- CTXN3 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101060666; called by muse, mutect2, varscan2
- CUL3 | c.1735G>T p.G579C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV100024113, COSV52368296; called by muse, mutect2, varscan2
- CUL9 | c.5803G>T p.G1935C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99335238; called by muse, mutect2
- CUX2 | c.1683G>T p.Q561H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99919368; called by muse, mutect2, varscan2
- CWC22 | c.1073A>G p.D358G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99844172; called by muse, mutect2, varscan2
- CWH43 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99893238; called by muse, mutect2, varscan2
- CXCL16 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99543458; called by muse, mutect2, varscan2
- CXCR4 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99602791; called by muse, mutect2, varscan2
- CXorf38 | c.472-2A>G p.X158_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100010301; called by muse, mutect2, varscan2
- CXorf58 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753748456, COSV101002969; called by muse, mutect2
- CYB5R3 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349013; called by muse, mutect2, varscan2
- CYBB | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782094658, COSV66084889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYGB | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99506087; called by muse, mutect2
- CYP1A1 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101122272; called by muse, mutect2, varscan2
- CYP24A1 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99398232; called by muse, mutect2, varscan2
- CYP26B1 | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772601509, COSV99134446; called by muse, mutect2, varscan2
- CYP2A6 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs374515279; called by mutect2, varscan2
- CYP2J2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100967990; called by muse, mutect2, varscan2
- CYP4A11 | c.1037G>T p.R346M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100152316; called by muse, mutect2, varscan2
- CYP4F2 | c.1251C>T p.G417= | Splice Region (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99685901; called by muse, mutect2, varscan2
- CYRIA | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100838320; called by muse, mutect2
- CYTL1 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV100312384, COSV57037411; called by muse, mutect2, varscan2
- DAAM1 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1389496704, COSV100658315; called by muse, mutect2, varscan2
- DAB1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100139888; called by muse, mutect2, varscan2
4,636 further variants in this file (3,226 protein-altering or splice-affecting, 1,269 silent, 141 other) are not listed here.
